Somatic mutation profile of tumor specimen MMRF_1667_1_BM_CD138pos (aliquot MMRF_1667_1_BM_CD138pos_T2_KBS5U_K11907) from MMRF case MMRF_1667, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.7 years (21,086 days).
Specimen MMRF_1667_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 020a8c7e-8405-4886-8e1d-0b593a66fab5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1667_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1667_1_PB_Whole_C7_KBS5U_K11889; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f16e542a-42b2-4350-b86a-517e1a3152d5

The open-access MAF lists 97 somatic variants for this specimen: 38 protein-altering or splice-affecting, 16 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Intron 18, Silent 16, 3'UTR 15, 5'UTR 5, 3'Flank 2, RNA 2, Frame Shift Del 1, In Frame Del 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AATK | c.3961G>A p.A1321T (on ENST00000326724 / NM_001080395.3; = p.A1218T on NM_004920.2) | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as rs1344157189; called by muse, mutect2
- ADCY2 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs755729905; called by muse, varscan2
- CD70 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55566616; called by muse, mutect2, varscan2
- CGNL1 | c.2528G>A p.R843Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs150556311; called by muse, mutect2, varscan2
- CRISP1 | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV59995756; called by muse, mutect2, varscan2
- DCLK1 | c.674A>G p.K225R | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.988); catalogued as COSV55175885, COSV55179596; called by muse, mutect2, varscan2
- DUSP29 | c.26G>A p.S9N | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs776087998; called by muse, mutect2, varscan2
- FCSK | c.154A>T p.K52* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as rs1249940928; called by muse, mutect2, varscan2
- GFRA2 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.842); catalogued as rs1485341779; called by muse, mutect2, varscan2
- HOXA3 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 110/162 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100415690; called by muse, mutect2, varscan2
- IGKV1-5 | c.295A>G p.S99G | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.11); catalogued as rs576071225; called by muse, mutect2
- IGKV4-1 | c.359C>G p.T120S | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs749276071; called by muse, mutect2, varscan2
- LRP6 | c.3277C>T p.R1093W | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752896710, COSV53789294; called by muse, mutect2, varscan2
- LRRC3B | c.107A>C p.K36T | Missense Mutation (SNP) | VAF 83/196 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.211); catalogued as COSV67521300; called by muse, mutect2, varscan2
- LSM14A | c.342C>G p.F114L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV70884835; called by muse, mutect2, varscan2
- MAPK8IP3 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.826); catalogued as rs749671052, COSV51718818; called by muse, mutect2, varscan2
- PCSK5 | c.599C>A p.P200Q | Missense Mutation (SNP) | VAF 55/85 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100950220; called by muse, mutect2, varscan2
- RFX2 | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs761381900; called by muse, mutect2, varscan2
- RIMBP2 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs370817702; called by muse, varscan2
- UTP20 | c.5455G>A p.V1819I | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as rs768218728, COSV55378605; called by muse, mutect2, varscan2
- AGTR2 | c.953A>T p.Y318F | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C8orf34 | c.36G>C p.L12F | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2, varscan2
- CDK7 | c.884del p.F295Sfs*23 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | called by mutect2, pindel
- COL4A5 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- CT83 | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- DMXL2 | c.8726C>T p.A2909V | Missense Mutation (SNP) | VAF 108/342 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DSC1 | c.360G>C p.K120N | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- EVX2 | c.310C>A p.H104N | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- FBXL16 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HTT | c.4195A>G p.T1399A | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHV2-70 | c.297_320del p.V100_D107del | In Frame Del (DEL) | VAF 4/22 reads (18%) | called by pindel, varscan2
- IRF8 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- LAMP2 | c.727A>G p.I243V | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRP1B | c.3135A>T p.E1045D | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRK | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- SHANK1 | c.6437G>A p.G2146D | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAIP | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF816-ZNF321P | c.336C>A p.N112K | Missense Mutation (SNP) | VAF 72/277 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- AGBL5 | c.1794C>T p.R598= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- ARSL | c.1014C>T p.D338= | Silent (SNP) | VAF 12/24 reads (50%) | called by muse, varscan2
- CATSPER2 | c.633C>T p.I211= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV58660718; called by muse, mutect2, varscan2
- DAAM2 | c.2004A>G p.K668= | Silent (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- DLC1 | c.2637C>T p.Y879= (on ENST00000276297 / NM_001348081.2; = p.Y442= on NM_006094.5) | Silent (SNP) | VAF 8/160 reads (5%) | catalogued as COSV52288698; called by muse, mutect2
- DYNC2LI1 | c.327T>C p.F109= | Silent (SNP) | VAF 126/278 reads (45%) | catalogued as COSV53183428; called by muse, mutect2, varscan2
- IPO8 | c.1506G>A p.A502= | Silent (SNP) | VAF 55/128 reads (43%) | catalogued as rs1027360957; called by muse, mutect2, varscan2
- KIF26A | c.3981G>A p.T1327= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs1434059336; called by muse, mutect2, varscan2
- KLHDC7A | c.1977C>T p.A659= | Silent (SNP) | VAF 41/90 reads (46%) | catalogued as rs1378061584, COSV68770140; called by muse, mutect2, varscan2
- LRP1 | c.9415C>T p.L3139= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- OSBPL5 | c.1458C>T p.H486= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs764857249, COSV99719873; called by muse, mutect2, varscan2
- PCDHA2 | c.2073T>G p.A691= | Silent (SNP) | VAF 34/60 reads (57%) | called by muse, mutect2, varscan2
- PGS1 | c.486C>T p.L162= | Silent (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- TSHZ3 | c.192C>T p.A64= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs375736734, COSV53675522; called by muse, varscan2
- USP1 | c.1047C>G p.P349= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs760557373; called by muse, mutect2, varscan2
- VPS18 | c.855C>T p.A285= | Silent (SNP) | VAF 60/181 reads (33%) | called by muse, mutect2, varscan2
- ADIPOR2 | c.*1970C>G | 3'UTR (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- AGTPBP1 | c.*540T>G | 3'UTR (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- AKR7A2 | c.591+80del | Intron (DEL) | VAF 12/32 reads (38%) | called by mutect2, pindel, varscan2
- API5 | c.*1268G>A | 3'UTR (SNP) | VAF 77/222 reads (35%) | catalogued as rs772816851, COSV101124558; called by muse, mutect2, varscan2
- ARHGAP21 | c.495+367A>T | Intron (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- ARID1B | c.3511+78C>G | Intron (SNP) | VAF 55/74 reads (74%) | called by muse, mutect2, varscan2
- BMERB1 | c.*240T>C | 3'UTR (SNP) | VAF 49/116 reads (42%) | called by muse, mutect2, varscan2
- CDH15 | chr16:89168308 C>T | 5'Flank (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- CEP170P1 | n.4460C>T | RNA (SNP) | VAF 42/126 reads (33%) | called by muse, mutect2, varscan2
- DACH2 | c.1751-939T>C | Intron (SNP) | VAF 34/82 reads (41%) | called by muse, varscan2
- DACH2 | c.1751-796G>A | Intron (SNP) | VAF 45/94 reads (48%) | catalogued as COSV64160935; called by muse, varscan2
- DMGDH | c.2250+3008A>G | Intron (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- EPB41L4A | c.-119G>C | 5'UTR (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- GALT | c.378-44C>G | Intron (SNP) | VAF 83/261 reads (32%) | called by muse, mutect2, varscan2
- GRM5 | c.661+62490A>C | Intron (SNP) | VAF 74/184 reads (40%) | catalogued as COSV100555333; called by muse, mutect2, varscan2
- HELLPAR | n.203522A>G | RNA (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2
- KIF5C | c.291+122C>A | Intron (SNP) | VAF 50/114 reads (44%) | called by muse, mutect2, varscan2
- KLHL29 | c.-45-38046G>A | Intron (SNP) | VAF 25/47 reads (53%) | catalogued as rs978923767; called by muse, mutect2, varscan2
- KLHL6 | c.*3137G>A | 3'UTR (SNP) | VAF 44/134 reads (33%) | called by muse, mutect2, varscan2
- LRIT2 | c.*762C>T | 3'UTR (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- LTB | c.163-145G>C | Intron (SNP) | VAF 59/158 reads (37%) | catalogued as rs140984421, COSV53000853; called by muse, mutect2, varscan2
- MAGEB1 | c.*78T>A | 3'UTR (SNP) | VAF 27/48 reads (56%) | called by muse, mutect2, varscan2
- MAGT1 | c.672+104del | Intron (DEL) | VAF 16/27 reads (59%) | called by mutect2, varscan2
- MAP4 | chr3:47851545 T>A | 3'Flank (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- MAP4 | chr3:47851546 T>C | 3'Flank (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- MVB12B | c.*2407G>T | 3'UTR (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- NDUFAF3 | c.-5C>T | 5'UTR (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- PARVG | c.584-16G>A | Intron (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- PIK3CD | c.-138+1436T>G | Intron (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- POLA1 | c.2549-841_2549-840dup | Intron (INS) | VAF 11/26 reads (42%) | called by mutect2, varscan2
- PXDN | c.2104+70C>T | Intron (SNP) | VAF 111/253 reads (44%) | called by muse, mutect2, varscan2
- RAPGEF1 | c.*1408C>T | 3'UTR (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- RCAN2 | c.*162_*165del | 3'UTR (DEL) | VAF 25/56 reads (45%) | called by mutect2, pindel, varscan2
- RHOB | c.-265C>T | 5'UTR (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- SEL1L | c.*3239G>A | 3'UTR (SNP) | VAF 4/44 reads (9%) | catalogued as rs1034096400; called by muse, mutect2
- SH3RF1 | c.*1743_*1774delinsACAATGTATATTATGTTCCTGTGTGTTGAATTTA | 3'UTR (INS) | VAF 7/59 reads (12%) | called by pindel, varscan2*
- SHH | c.*443G>A | 3'UTR (SNP) | VAF 29/96 reads (30%) | catalogued as rs1376452195; called by muse, mutect2, varscan2
- SIMC1 | c.-255T>A | 5'UTR (SNP) | VAF 8/17 reads (47%) | catalogued as rs866802577; called by muse, mutect2, varscan2
- SLC25A14 | c.594+29A>C | Intron (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- SLC35D3 | c.*82G>A | 3'UTR (SNP) | VAF 43/94 reads (46%) | called by muse, mutect2, varscan2
- SLC47A1 | c.*179A>C | 3'UTR (SNP) | VAF 51/116 reads (44%) | called by muse, mutect2, varscan2
- SNRPN | c.-357C>G | 5'UTR (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- ZC4H2 | c.54-94A>C | Intron (SNP) | VAF 66/172 reads (38%) | called by muse, mutect2, varscan2
